Somatic mutation profile of tumor specimen TCGA-HU-A4G8-01A (aliquot TCGA-HU-A4G8-01A-11D-A25D-08) from TCGA case TCGA-HU-A4G8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,254 days).
Specimen TCGA-HU-A4G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53714e92-a870-48d2-a087-a876b0b8dbe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4G8-10A (Blood Derived Normal), aliquot TCGA-HU-A4G8-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c09872a0-b969-42e3-8c68-7495e6a95a61

The open-access MAF lists 1,793 somatic variants for this specimen: 1,372 protein-altering or splice-affecting, 395 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 907, Silent 395, Frame Shift Del 317, Frame Shift Ins 53, Nonsense Mutation 40, Splice Region 18, Splice Site 17, In Frame Del 14, RNA 9, Intron 7, Translation Start Site 4, 3'UTR 4.

Variants (750 of 1,793; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 75/300 reads (25%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A2 | c.4039+1G>A p.X1347_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as rs1555333502, COSV64628521; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLG | c.477del p.E160Kfs*34 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNB1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs1557889974, COSV66100613; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNE | c.479G>A p.R160Q (on ENST00000396594 / NM_001128227.3; = p.R129Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as rs748704459, CM042357, COSV64951970; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HPS4 | c.57dup p.L20Sfs*3 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs281865097; ClinVar: pathogenic; called by mutect2, varscan2
- ITGA7 | c.1220del p.G407Vfs*143 (on ENST00000555728; = p.G363Vfs*143 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as rs587780362, COSV57691242, COSV57699409; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- JUP | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782440692, CM117932, COSV60278113; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- LAS1L | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1057518699, CM151024, COSV56707416; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 56/125 reads (45%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- PPT1 | c.547G>A p.E183K (on ENST00000433473; = p.E184K on NM_000310.4) | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs386833655, CM981633, COSV65655081; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZNF649 | c.594A>C p.R198S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.323); catalogued as COSV100030986, COSV56816046; called by muse, mutect2, varscan2
- AASDHPPT | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs776262908, COSV53788251; called by muse, mutect2, varscan2
- ABCA2 | c.6585G>T p.R2195= (on ENST00000614293; = p.R2165= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55801759; called by muse, mutect2
- ABCA2 | c.987+2T>C p.X329_splice (on ENST00000614293; = p.X299_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV55801770; called by muse, mutect2, varscan2
- ABCA7 | c.988A>G p.M330V | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54029996; called by muse, varscan2
- ABCB7 | c.566C>T p.A189V (on ENST00000373394 / NM_001271696.3; = p.A190V on NM_004299.6) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV53719999; called by muse, mutect2, varscan2
- ABCC8 | c.2597A>G p.H866R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV56850987; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs754984711, COSV53685775; called by muse, mutect2, varscan2
- ABHD3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs772556503, COSV56676679; called by muse, mutect2, varscan2
- ABI1 | c.1434_1436del p.K478del | In Frame Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1235424163; called by pindel, varscan2
- AC013489.1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as rs745794211, COSV51550752; called by muse, mutect2, varscan2
- AC090517.4 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50997129; called by muse, mutect2, varscan2
- ACOT11 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs760640782, COSV56364300; called by muse, mutect2, varscan2
- ACSL1 | c.1054A>G p.M352V | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV55662849; called by muse, mutect2, varscan2
- ACTG2 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.07); catalogued as rs199696794; called by muse, mutect2, varscan2
- ACTN1 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.15); catalogued as rs763573834, COSV51992283; called by muse, mutect2, varscan2
- ACTN3 | c.2562del p.E855Rfs*52 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | catalogued as rs763539773; called by mutect2, pindel, varscan2
- ACTN4 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1031037100, COSV53142731; called by muse, mutect2, varscan2
- ACTR1A | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs778045034, COSV64023355; called by muse, mutect2, varscan2
- ACTRT3 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV57754426; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 37/87 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS1 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53168852; called by muse, mutect2, varscan2
- ADAMTS12 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs550821902, COSV61263538; called by muse, mutect2, varscan2
- ADAMTS19 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV50749688; called by muse, mutect2, varscan2
- ADAMTS19 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 35/188 reads (19%) | catalogued as rs772148624, COSV50749719, COSV50758055; called by muse, mutect2, varscan2
- ADAMTS6 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV66859951; called by muse, mutect2, varscan2
- ADAMTSL4 | c.713_716del p.T238Rfs*31 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs775965947; called by pindel, varscan2
- ADAP1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.675); catalogued as rs1362513013, COSV56213682; called by muse, mutect2, varscan2
- ADARB2 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs138785387; called by muse, mutect2, varscan2
- ADCY5 | c.1876G>A p.G626S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1350109265, COSV59198349; called by muse, mutect2, varscan2
- ADCY7 | c.2416T>C p.F806L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV54267023; called by muse, varscan2
- ADCY8 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53909037; called by muse, mutect2, varscan2
- ADD2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV52461543; called by muse, mutect2
- ADGRB1 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs757292289, COSV60096964; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRV1 | c.626del p.P209Lfs*6 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs756977835, COSV101316537, COSV67977494; called by mutect2, pindel, varscan2
- ADRA1B | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV60701874; called by muse, mutect2, varscan2
- ADRB3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV61461924; called by muse, mutect2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as COSV58317085; called by mutect2, pindel, varscan2
- AGO2 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.608); catalogued as COSV55047705; called by muse, mutect2, varscan2
- AHCTF1 | c.553C>T p.R185* (on ENST00000366508; = p.R159* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58252336; called by muse, mutect2, varscan2
- AHR | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54121818; called by muse, mutect2, varscan2
- AK4 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100519730; called by muse, mutect2, varscan2
- AKAP1 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs775916699, COSV58470490; called by muse, mutect2, varscan2
- AKAP12 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149275104; called by muse, mutect2, varscan2
- AKAP9 | c.11751A>G p.I3917M (on ENST00000359028; = p.I3893M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV50151832; called by muse, mutect2
- ALDH18A1 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64662639; called by muse, mutect2, varscan2
- ALDH8A1 | c.1377del p.M460* | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1423245247, COSV99664569; called by mutect2, pindel, varscan2
- ALDOC | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52024578; called by muse, mutect2, varscan2
- ALPK3 | c.2537del p.G846Efs*12 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV51934219; called by mutect2, pindel, varscan2
- AMER2 | c.1639del p.R547Gfs*38 | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | catalogued as COSV100766255, COSV63436953; called by mutect2, pindel, varscan2
- AMER2 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100766442, COSV63437692; called by muse, mutect2, varscan2
- AMPD3 | c.1567T>C p.F523L (on ENST00000396553 / NM_001025389.2; = p.F532L on NM_000480.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV67331039; called by muse, mutect2, varscan2
- ANAPC2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs146337536; called by muse, mutect2, varscan2
- ANGEL2 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV64737417; called by muse, mutect2, varscan2
- ANK1 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs775089579, COSV55882355; called by muse, mutect2, varscan2
- ANK2 | c.11480A>G p.Q3827R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as rs1554590231, COSV52162459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.12278G>T p.R4093M (on ENST00000280772 / NM_001320874.2; = p.R614M on NM_001149.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55059408; called by muse, mutect2, varscan2
- ANKAR | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV55613016; called by muse, mutect2, varscan2
- ANKFY1 | c.3137C>T p.T1046M (on ENST00000341657 / NM_001330063.2; = p.T1047M on NM_016376.5) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431844636, COSV58917796; called by muse, mutect2, varscan2
- ANKH | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772363889, COSV52481188; called by muse, mutect2, varscan2
- ANKRD11 | c.5630del p.P1877Rfs*86 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as COSV56357612; called by mutect2, pindel, varscan2
- ANKRD26 | c.4976del p.N1659Ifs*2 | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | catalogued as rs762275496; called by mutect2, pindel, varscan2
- ANKRD30A | c.211G>A p.A71T (on ENST00000611781; = p.A15T on NM_052997.2) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.251); catalogued as rs751095111, COSV64607883; called by muse, mutect2, varscan2
- ANKRD34A | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60160994; called by muse, mutect2, varscan2
- ANKRD49 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV57060158; called by muse, mutect2, varscan2
- ANO4 | c.671C>T p.T224I (on ENST00000392977 / NM_001286615.2; = p.T189I on NM_178826.4) | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV54588178, COSV54596642; called by muse, mutect2, varscan2
- AP1B1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766149155, COSV58017873; called by muse, mutect2, varscan2
- APBA1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.987); catalogued as rs763263675, COSV55225948; called by muse, varscan2
- APBA1 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV55228468; called by muse, varscan2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 20/126 reads (16%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APLP2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1342621835, COSV53840918; called by muse, mutect2, varscan2
- APOBEC1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99980947; called by muse, mutect2, varscan2
- APOBEC3B | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs551433639, COSV59841688; called by muse, mutect2, varscan2
- APOL2 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV50772133, COSV50772398; called by muse, mutect2, varscan2
- AQP10 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.869); catalogued as COSV61475093; called by muse, mutect2, varscan2
- AQR | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50035232; called by muse, mutect2, varscan2
- ARAP1 | c.973G>A p.V325I (on ENST00000393609 / NM_001040118.2; = p.V80I on NM_015242.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs750657269, COSV61991302; called by muse, mutect2, varscan2
- ARF5 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV50001048, COSV50001084; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGAP29 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs770096777, COSV53112228; called by muse, mutect2, varscan2
- ARHGAP44 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52394460; called by muse, mutect2, varscan2
- ARHGAP45 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs758072591, COSV57432201; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 42/160 reads (26%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.3934C>T p.Q1312* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as rs1554234402, COSV51662440; called by muse, mutect2, varscan2
- ARPC2 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV55284994; called by muse, mutect2
- ARPP19 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV51119313; called by muse, mutect2, varscan2
- ARRB1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs779500908, COSV63575629; called by muse, mutect2, varscan2
- ASCC2 | c.2116A>G p.S706G | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs939326269, COSV57073964; called by muse, mutect2, varscan2
- ASH1L | c.3617A>T p.D1206V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64208242; called by muse, mutect2, varscan2
- ASPG | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs532981359, COSV71933792; called by muse, mutect2, varscan2
- ASTN1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56064345; called by muse, mutect2
- ASXL3 | c.6347C>T p.A2116V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as rs757112357, COSV52466903, COSV52470266; called by muse, mutect2, varscan2
- ATAD3B | c.292A>G p.N98D (on ENST00000308647; = p.N152D on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV58020881; called by muse, mutect2, varscan2
- ATF7IP2 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV61093561; called by muse, mutect2, varscan2
- ATG2A | c.2866G>A p.G956R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755811737, COSV65966956; called by muse, mutect2, varscan2
- ATP10B | c.2455C>T p.R819* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as rs1190281425, COSV59152552; called by muse, mutect2, varscan2
- ATP1A4 | c.1791G>A p.M597I | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV63626603, COSV99058487; called by muse, mutect2, varscan2
- ATP5F1B | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56261053; called by muse, mutect2, varscan2
- ATP6AP1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs782516905, COSV62340856; called by muse, mutect2, varscan2
- ATP8A2 | c.1367T>C p.L456S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.605); catalogued as COSV54953177; called by muse, mutect2, varscan2
- ATXN1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1482070456, COSV55209847; called by muse, varscan2
- AXDND1 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as rs754952987, COSV62642121; called by muse, mutect2, varscan2
- AZU1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376150747, COSV52141075; called by muse, mutect2, varscan2
- B4GALNT4 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as rs1311621009, COSV57321443, COSV57322682; called by muse, mutect2, varscan2
- B4GALT7 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.087); catalogued as COSV50353349; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAHD1 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV69084026; called by muse, mutect2, varscan2
- BCAT1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs774269366, COSV53911623; called by muse, mutect2, varscan2
- BCL9 | c.4193del p.P1398Hfs*3 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as COSV52345783; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEST2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866786611, COSV50365248; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP2 | c.420del p.T141Rfs*21 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as COSV66578762; called by mutect2, pindel, varscan2
- BMPER | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51819123; called by muse, mutect2, varscan2
- BMPR2 | c.46T>C p.W16R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV65809602; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BMS1 | c.2227del p.H743Mfs*5 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | catalogued as COSV65734081, COSV65734954; called by mutect2, pindel, varscan2
- BRCA2 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as rs786202205, COSV66454271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD7 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV67158855; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 10/30 reads (33%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1162365779, COSV56292321, COSV56294001; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD17 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV64729864; called by muse, mutect2, varscan2
- BTBD9 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs771371697, COSV58426427; called by muse, mutect2, varscan2
- BZW1 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100729859, COSV63349736; called by muse, mutect2, varscan2
- C11orf24 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs762931895, COSV58505649; called by muse, mutect2, varscan2
- C15orf39 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs781585751, COSV62296773; called by muse, mutect2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | catalogued as rs752496395; called by mutect2, varscan2
- C3 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs765999872, COSV55573531; called by muse, mutect2, varscan2
- C5orf49 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV67708558; called by muse, mutect2, varscan2
- C6orf89 | c.599G>A p.C200Y (on ENST00000373685; = p.C207Y on NM_152734.4) | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV62101923; called by muse, mutect2, varscan2
- C7orf50 | c.534_535del p.L179Afs*53 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CABP2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753361851, COSV53708883; called by muse, mutect2, varscan2
- CACNA1E | c.6616T>C p.C2206R (on ENST00000367573 / NM_001205293.3; = p.C2163R on NM_000721.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV62396682; called by muse, mutect2, varscan2
- CACNA1S | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV62941418; called by muse, mutect2, varscan2
- CACNG1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs200686073, COSV56826863; called by muse, mutect2, varscan2
- CAD | c.4610C>T p.A1537V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV53027178; called by muse, mutect2, varscan2
- CALB2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100226083, COSV56939553; called by muse, mutect2, varscan2
- CAPN3 | c.598T>A p.F200I | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD982533, COSV58822349; called by muse, mutect2, varscan2
- CAPN5 | c.1342C>T p.R448W (on ENST00000456580; = p.R408W on NM_004055.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs374843302; called by muse, mutect2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CASK | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59367037; called by muse, mutect2, varscan2
- CASKIN2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs370283661, COSV100395551; called by muse, mutect2, varscan2
- CASS4 | c.2134G>T p.V712L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV64386624; called by muse, mutect2, varscan2
- CASZ1 | c.5034G>C p.E1678D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV65458017; called by muse, mutect2, varscan2
- CATSPER3 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV50946582; called by muse, mutect2, varscan2
- CATSPER4 | c.1401del p.K467Nfs*78 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs769908264; called by mutect2, varscan2
- CAVIN4 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs755935790, COSV56867244; called by muse, mutect2, varscan2
- CBLIF | c.1035_1037del p.V346del | In Frame Del (DEL) | VAF 44/152 reads (29%) | catalogued as rs762845250; called by pindel, varscan2
- CCAR2 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV52383737, COSV52384686; called by muse, mutect2, varscan2
- CCDC150 | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV55874572; called by muse, mutect2, varscan2
- CCDC171 | c.2968C>T p.R990C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753856863, COSV52641994; called by muse, mutect2, varscan2
- CCDC198 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV53602154; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC74B | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV60102279; called by muse, mutect2, varscan2
- CCDC88A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1469234270, COSV55061994; called by muse, mutect2, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD58 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59841807; called by muse, mutect2, varscan2
- CD81 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55132957; called by muse, mutect2, varscan2
- CDC42BPB | c.3536C>T p.T1179M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs369632217; called by muse, mutect2, varscan2
- CDH17 | c.1783G>T p.G595C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50328844; called by muse, mutect2, varscan2
- CDH23 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs535416598, COSV54955861; called by muse, mutect2, varscan2
- CDH9 | c.1889T>C p.V630A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV50290634; called by muse, mutect2
- CDHR2 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 115/433 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56136069; called by muse, mutect2, varscan2
- CDK13 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV51700150; called by muse, mutect2, varscan2
- CDK5RAP2 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769512516, COSV62574448; called by muse, mutect2
- CELA1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV53329995; called by muse, mutect2, varscan2
- CELSR3 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as COSV50842354, COSV50862785; called by muse, mutect2, varscan2
- CEMIP | c.540del p.F180Lfs*44 | Frame Shift Del (DEL) | VAF 44/213 reads (21%) | catalogued as rs753314096; called by mutect2, pindel, varscan2
- CENPE | c.4621A>G p.S1541G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as rs1229860087, COSV54381543; called by muse, mutect2, varscan2
- CEP128 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as COSV53674918; called by muse, mutect2, varscan2
- CEP164 | c.3803T>G p.L1268R | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54041575; called by muse, varscan2
- CEP164 | c.3947G>A p.G1316D | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV54041585; called by muse, varscan2
- CEP78 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781363287, COSV52846874; called by muse, mutect2, varscan2
- CES5A | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747900232, COSV51866615; called by muse, mutect2, varscan2
- CFAP58 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as COSV57212256; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs763364101; called by mutect2, varscan2
- CHD2 | c.5477G>A p.R1826Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV67706833; called by muse, mutect2, varscan2
- CHD4 | c.4913C>T p.A1638V (on ENST00000357008 / NM_001363606.2; = p.A1649V on NM_001273.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58901568; called by muse, mutect2, varscan2
- CHD6 | c.4872G>T p.Q1624H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as COSV64690988; called by muse, mutect2, varscan2
- CHD7 | c.6158G>A p.R2053Q | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV71110838; called by muse, mutect2, varscan2
- CHERP | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs1279805684, COSV52224611; called by muse, mutect2, varscan2
- CHFR | c.1912G>A p.G638S (on ENST00000432561 / NM_001161345.1; = p.G597S on NM_018223.2) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57174529; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766076436, COSV58775382; called by muse, mutect2, varscan2
- CHST12 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1196946734, COSV51673995, COSV51675495; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CHST5 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1157574032, COSV60339323; called by muse, mutect2, varscan2
- CHST8 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52859080; called by muse, mutect2, varscan2
- CIC | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV50573951; called by muse, mutect2, varscan2
- CLASP1 | c.3692dup p.S1232* | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs749719822; called by mutect2, varscan2
- CLIP4 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV60749295; called by muse, mutect2, varscan2
- CLK3 | c.755G>A p.R252H (on ENST00000395066 / NM_001130028.1; = p.R104H on NM_003992.4) | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as rs1429799732, COSV61412783; called by muse, mutect2, varscan2
- CLMN | c.2511+2T>C p.X837_splice | Splice Site (SNP) | VAF 27/105 reads (26%) | catalogued as COSV54182490; called by muse, mutect2, varscan2
- CLOCK | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59402044; called by muse, mutect2, varscan2
- CLRN2 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99845649; called by muse, mutect2, varscan2
- CMTM7 | c.313T>C p.C105R | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV58550863; called by muse, mutect2, varscan2
- CMYA5 | c.6876del p.E2293Kfs*9 | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | catalogued as rs745742163; called by mutect2, pindel, varscan2
- CNDP2 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV60840029; called by muse, mutect2, varscan2
- CNGA2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV61704623; called by muse, mutect2, varscan2
- CNOT8 | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.037); catalogued as COSV53585589; called by muse, mutect2, varscan2
- CNPY2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as rs762509546, COSV56264398; called by muse, mutect2, varscan2
- CNR1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1482444652, COSV100759136; called by muse, mutect2, varscan2
- COG6 | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs773379601, COSV62996086; called by muse, mutect2, varscan2
- COL11A1 | c.1635dup p.P546Afs*9 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs779795373; called by mutect2, varscan2
- COL16A1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs572974202, COSV54700896; called by muse, mutect2, varscan2
- COL5A2 | c.3400G>A p.G1134R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410014; called by muse, mutect2, varscan2
- COL9A2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs1221599181, COSV101028747, COSV65622869; called by muse, mutect2, varscan2
- COLQ | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774638847, COSV67524867; called by muse, mutect2, varscan2
- COP1 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58167602; called by muse, mutect2, varscan2
- COPG1 | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV59114255; called by muse, mutect2, varscan2
- COPRS | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773669721, COSV56632890; called by muse, mutect2, varscan2
- COPS8 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV62976271; called by muse, mutect2, varscan2
- COQ3 | c.732C>T p.P244= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as rs369408410, COSV99632698; called by muse, mutect2
- CORO2A | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs544067311, COSV59663282; called by muse, mutect2, varscan2
- COX10 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV55405237; called by muse, mutect2, varscan2
- COX11 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV54802851, COSV54802988; called by muse, mutect2, varscan2
- CPA1 | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163206; called by muse, mutect2, varscan2
- CPAMD8 | c.3341C>T p.P1114L (on ENST00000651564; = p.P1067L on NM_015692.5) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs200032712, COSV71595723; called by muse, mutect2, varscan2
- CPB2 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51674287; called by muse, mutect2, varscan2
- CPN2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757077951, COSV60470480; called by muse, mutect2, varscan2
- CPT1B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377484724; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRAT | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58877155; called by muse, mutect2, varscan2
- CRYBG3 | c.7634A>T p.D2545V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV51712090; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as rs760194024, COSV65675647; called by muse, mutect2, varscan2
- CSMD1 | c.2513T>A p.L838H (on ENST00000520002; = p.L837H on NM_033225.6) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59327706; called by muse, mutect2, varscan2
- CSMD3 | c.8318C>A p.T2773N (on ENST00000297405 / NM_001363185.1; = p.T2604N on NM_052900.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV52187743; called by muse, mutect2, varscan2
- CSPG4 | c.4870C>T p.R1624W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs762365316, COSV57892632; called by muse, mutect2, varscan2
- CSTF3 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.036); catalogued as COSV60611420; called by muse, mutect2, varscan2
- CTR9 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV63727910, COSV63728501; called by muse, mutect2
- CUBN | c.4699T>C p.Y1567H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV64716333; called by muse, mutect2, varscan2
- CUL7 | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1033757918, COSV54817318; called by muse, mutect2
- CYB5R1 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV65916996; called by muse, mutect2, varscan2
- CYLC1 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61412343; called by muse, mutect2, varscan2
- CYP19A1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202076619, COSV53059469; called by muse, mutect2, varscan2
- DAG1 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs556413209, COSV58184513; called by muse, mutect2, varscan2
- DCAF12L1 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as COSV64421817, COSV64421896; called by muse, mutect2, varscan2
- DCAF5 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs139500055, COSV58460453; called by muse, mutect2, varscan2
- DCLK1 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV55187797; called by muse, mutect2, varscan2
- DCLRE1B | c.22del p.H8Ifs*75 | Frame Shift Del (DEL) | VAF 38/181 reads (21%) | catalogued as COSV56727015; called by mutect2, pindel, varscan2
- DCT | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745397768, COSV65468809; called by muse, mutect2, varscan2
- DDB2 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs139325563, COSV57038783; called by muse, mutect2, varscan2
- DDX1 | c.383T>C p.L128S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV51840088; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX55 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV53016219; called by muse, mutect2, varscan2
- DENND1B | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV52464917; called by muse, mutect2, varscan2
- DENND4B | c.2725C>G p.Q909E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1051365359; called by mutect2, varscan2
- DENND4C | c.1751T>C p.I584T | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV66822206; called by muse, mutect2, varscan2
- DHX16 | c.2899_2902del p.T967Sfs*24 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs755421363; called by mutect2, pindel, varscan2
- DHX32 | c.705A>G p.I235M | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.216); catalogued as COSV52940321; called by muse, mutect2, varscan2
- DHX34 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866935357, COSV60895503; called by muse, mutect2, varscan2
- DHX38 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs963971164, COSV51697813; called by muse, mutect2, varscan2
- DIS3L | c.1234C>T p.R412C (on ENST00000319212 / NM_001143688.3; = p.R329C on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs773245840, COSV59912284; called by muse, mutect2, varscan2
- DLG2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as rs1414599025, COSV54646625; called by muse, mutect2, varscan2
- DLGAP2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70098655; called by muse, mutect2, varscan2
- DLX3 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV71547651; called by muse, mutect2, varscan2
- DMBX1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV63602055; called by muse, mutect2, varscan2
- DMWD | c.1366del p.L456Wfs*203 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs746317972; called by mutect2, varscan2
- DNAAF3 | c.151C>A p.L51I (on ENST00000524407 / NM_001256715.2; = p.L98I on NM_178837.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV66993113; called by muse, mutect2, varscan2
- DNAH10 | c.5077C>T p.R1693W (on ENST00000409039; = p.R1632W on NM_207437.3) | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs372793754; called by muse, mutect2, varscan2
- DNAH17 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as rs775795439, COSV67754876; called by muse, mutect2
- DNAH2 | c.12269G>A p.G4090D | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV66719923; called by muse, mutect2, varscan2
- DNAH9 | c.4746A>T p.R1582S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV52350887; called by muse, mutect2, varscan2
- DNAH9 | c.5369T>C p.V1790A | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52350895; called by muse, mutect2, varscan2
- DNAJC1 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV65411160; called by muse, mutect2, varscan2
- DNAJC10 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51138721; called by muse, mutect2
- DNAJC5 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62671718; called by muse, mutect2, varscan2
- DNER | c.1147+2T>A p.X383_splice | Splice Site (SNP) | VAF 26/123 reads (21%) | catalogued as COSV59166878; called by muse, mutect2, varscan2
- DNM2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746387165, COSV58958954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DNMT3A | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.865); catalogued as COSV53045299, COSV53053441; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.4926G>A p.L1642= | Splice Region (SNP) | VAF 52/263 reads (20%) | catalogued as COSV52402450; called by muse, mutect2, varscan2
- DOCK8 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV66634137; called by muse, mutect2, varscan2
- DOP1B | c.6159A>G p.Q2053= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV67693492; called by muse, mutect2, varscan2
- DPF3 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV63500358; called by muse, mutect2, varscan2
- DRG2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs913404985, COSV56728317; called by muse, mutect2, varscan2
- DROSHA | c.4094_4095dup p.P1366Sfs*24 | Frame Shift Ins (INS) | VAF 17/102 reads (17%) | catalogued as rs1561100337; called by mutect2, varscan2
- DST | c.17223del p.K5741Nfs*2 (on ENST00000361203 / NM_001374722.1; = p.K3438Nfs*2 on NM_015548.5) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs756726565; called by mutect2, varscan2
- DUS1L | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs778657338, COSV57649088; called by muse, mutect2, varscan2
- DUSP11 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144123904, COSV99731103; called by muse, mutect2, varscan2
- DUXA | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73729712; called by muse, mutect2, varscan2
- DYRK1B | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV59913735; called by muse, mutect2, varscan2
- DYSF | c.6096C>A p.Y2032* | Nonsense Mutation (SNP) | VAF 41/142 reads (29%) | catalogued as rs1012723902, CM154274, COSV50356803; called by muse, mutect2, varscan2
- EAF1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV67657268; called by muse, mutect2, varscan2
- EDAR | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781652310, COSV51503008; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EDEM3 | c.2290A>G p.M764V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58924607; called by muse, mutect2, varscan2
- EFHB | c.2420_2422del p.G807del | In Frame Del (DEL) | VAF 28/105 reads (27%) | catalogued as rs751749423; called by pindel, varscan2
- EFHC1 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV64136451; called by muse, mutect2, varscan2
- EFTUD2 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68182738; called by muse, mutect2, varscan2
- EHMT2 | c.3128A>G p.Y1043C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV57667313; called by muse, mutect2
- EIF2B3 | c.1165A>G p.N389D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV64517500; called by muse, mutect2, varscan2
- EIF3G | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1315028177, COSV53458560; called by muse, mutect2, varscan2
- ELAVL4 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1169691831, COSV63915978; called by muse, mutect2, varscan2
- ELMO2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769240700, COSV51683135, COSV51685195; called by muse, mutect2, varscan2
- ELOVL3 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV64174511; called by muse, mutect2, varscan2
- ELP1 | c.3855G>T p.P1285= | Splice Region (SNP) | VAF 20/85 reads (24%) | catalogued as COSV101010341, COSV65897854; called by muse, mutect2, varscan2
- ENAH | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs375992317, COSV52868146; called by muse, mutect2, varscan2
- ENDOD1 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as rs1432124632, COSV53589590; called by muse, mutect2, varscan2
- ENPP1 | c.2285T>C p.I762T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.219); catalogued as COSV62932492; called by muse, mutect2, varscan2
- ENPP6 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs774718991, COSV57068314; called by muse, mutect2, varscan2
- EP400 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV57772843; called by muse, mutect2, varscan2
- EPB41L5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs375523508, COSV55356211; called by muse, mutect2, varscan2
- EPB42 | c.1660C>T p.R554* (on ENST00000441366 / NM_001114134.2; = p.R584* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as rs765829996, COSV55748967; called by muse, mutect2, varscan2
- EPHA10 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764448343, COSV60403003, COSV60403387; called by muse, mutect2, varscan2
- EPHA6 | c.3335G>A p.S1112N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1451930097, COSV67573059; called by muse, mutect2, varscan2
- EPHX1 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs755904769, COSV55301039; called by mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 14/38 reads (37%) | catalogued as rs768793415; called by mutect2, varscan2
- ESCO2 | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV59414664; called by muse, mutect2, varscan2
- ESPNL | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54541367; called by muse, mutect2, varscan2
- ESR1 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52791363; called by muse, mutect2, varscan2
- EWSR1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs751377720, COSV58421918; called by muse, mutect2, varscan2
- F8 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782158350, COSV64273781; called by muse, mutect2, varscan2
- F8A1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100371437; called by mutect2, varscan2
- FAHD2A | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770319428, COSV51978247; called by muse, mutect2, varscan2
- FAM131B | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372106778; called by muse, mutect2, varscan2
- FAM135A | c.3179G>A p.S1060N (on ENST00000370479 / NM_001351599.1; = p.S847N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52051851; called by muse, mutect2, varscan2
- FAM160A2 | c.2792T>C p.F931S (on ENST00000449352 / NM_001098794.2; = p.F945S on NM_032127.4) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56411581; called by muse, mutect2, varscan2
- FAM199X | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs1556379643, COSV55433619; called by muse, mutect2, varscan2
- FAM83H | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.594); catalogued as rs369020291, COSV66354403; called by muse, mutect2, varscan2
- FANCD2 | c.4183C>T p.Q1395* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV55038276; called by muse, mutect2, varscan2
- FANCE | c.524del p.G175Afs*4 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs773363446; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- FAT1 | c.5494G>A p.V1832I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV71674256; called by muse, mutect2, varscan2
- FAT4 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101271814, COSV67887318; called by muse, mutect2, varscan2
- FBN2 | c.3045del p.V1016Ffs*91 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | catalogued as COSV52517538; called by pindel, varscan2
- FBXL12 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as rs764357962, COSV56114195; called by muse, mutect2, varscan2
- FBXL6 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs781994383, COSV57351990; called by muse, mutect2, varscan2
- FBXO31 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs778618544, COSV61149032; called by muse, mutect2, varscan2
- FCER2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60916506; called by muse, mutect2
- FCGRT | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs779240739, COSV54542108; called by muse, mutect2, varscan2
- FCHSD1 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.077); catalogued as COSV99781116; called by muse, mutect2, varscan2
- FDFT1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs772157622, COSV99594541; called by muse, mutect2, varscan2
- FER1L6 | c.4092G>A p.A1364= | Splice Region (SNP) | VAF 15/83 reads (18%) | catalogued as rs567443286, COSV67550091; called by muse, mutect2, varscan2
- FERD3L | c.319A>G p.N107D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51762820, COSV51763096; called by muse, mutect2, varscan2
- FERMT1 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs150581071; ClinVar: uncertain significance; called by muse, varscan2
- FGB | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs571624045, COSV57418511, COSV57419244; called by muse, mutect2, varscan2
- FGFBP1 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1257385305, COSV52586520; called by muse, mutect2, varscan2
- FIBP | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57033760; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 28/163 reads (17%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FKBP15 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs771241869, COSV53035085; called by mutect2, varscan2
- FLNA | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV61043516; called by muse, mutect2, varscan2
- FLNB | c.6685G>A p.A2229T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as rs754754415, COSV55869317, COSV55880728; called by muse, mutect2, varscan2
- FLNB | c.6844G>A p.A2282T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as rs1339176246, COSV55880272; called by muse, mutect2, varscan2
- FLT3LG | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52619220; called by muse, mutect2, varscan2
- FN1 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs749462589, COSV60553582; called by muse, mutect2, varscan2
- FN1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV60548120; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs776730128; called by mutect2, pindel, varscan2
- FOXB1 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV101249641; called by muse, mutect2, varscan2
- FOXB2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65022997; called by muse, mutect2, varscan2
- FOXD4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58700394; called by muse, mutect2
- FOXD4L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as rs1395749842, COSV52074391; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs752351689; called by mutect2, pindel
- FRS2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs762081662, COSV54726117; called by muse, mutect2, varscan2
- FRY | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 149/411 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.833); catalogued as COSV66570544; called by muse, mutect2, varscan2
- FSIP2 | c.17354A>G p.K5785R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV100553637; called by mutect2, varscan2
- FSIP2 | c.18751A>G p.N6251D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV100553638; called by muse, mutect2, varscan2
- FURIN | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51576926; called by muse, mutect2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs756304971; called by mutect2, varscan2
- FXR2 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100007177, COSV51518783; called by muse, mutect2, varscan2
- FZD10 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV57473678, COSV99969588; called by muse, mutect2, varscan2
- FZD8 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV65967900; called by muse, mutect2, varscan2
- GABRQ | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs782042263, COSV64782116, COSV64782717; called by muse, mutect2, varscan2
- GAL3ST4 | c.696del p.R233Efs*90 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | catalogued as rs1562954447; called by mutect2, varscan2
- GALNT1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1205136450, COSV52452427; called by muse, mutect2, varscan2
- GALNT18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.071); catalogued as rs746409394, COSV57149603, COSV99924144; called by muse, mutect2, varscan2
- GALR3 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV50764024; called by muse, mutect2, varscan2
- GAS6 | c.422_424del p.F141del | In Frame Del (DEL) | VAF 73/186 reads (39%) | catalogued as rs749481576; called by pindel, varscan2
- GASK1B | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as COSV56707502; called by muse, mutect2, varscan2
- GCN1 | c.6104C>A p.T2035N | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV56108152; called by muse, mutect2, varscan2
- GCN1 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs981778548, COSV56107837; called by muse, mutect2, varscan2
- GFOD1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.389); catalogued as COSV64954736; called by muse, mutect2, varscan2
- GGN | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as rs761627725, COSV53057065; called by muse, mutect2
- GHSR | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV53839566; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs763147690; called by mutect2, varscan2
- GLDN | c.1331G>A p.G444D | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as COSV59090357; called by muse, mutect2, varscan2
- GNAI2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs782631757, COSV56494090; called by muse, mutect2, varscan2
- GNPDA2 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV54946804; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as rs370114090; called by mutect2, varscan2
- GP1BA | c.1480del p.T494Pfs*59 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as rs759573909; called by mutect2, pindel, varscan2
- GPAM | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.972); catalogued as rs760613531, COSV62081196; called by muse, mutect2, varscan2
- GPAT4 | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV67840890; called by muse, mutect2, varscan2
- GPCPD1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781457048, COSV66830838; called by muse, mutect2, varscan2
- GPR139 | c.57del p.G20Afs*27 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV58504119; called by mutect2, varscan2
- GPR156 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as COSV59940025; called by muse, mutect2, varscan2
- GPR25 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760153628, COSV58497953; called by muse, mutect2, varscan2
- GPR25 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV58498204; called by muse, varscan2
- GPR39 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV61423676; called by muse, mutect2, varscan2
- GPR45 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs199769227, COSV51524182; called by muse, mutect2, varscan2
- GRHL3 | c.984G>T p.E328D (on ENST00000350501 / NM_198174.3; = p.E333D on NM_021180.3) | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV52566885; called by muse, mutect2, varscan2
- GRIA1 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.203); catalogued as rs759723813, COSV53604100; called by muse, mutect2, varscan2
- GRIA1 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV53604118; called by muse, mutect2, varscan2
- GRIN2B | c.2454G>T p.M818I | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV74206006; called by muse, mutect2, varscan2
- GRK5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs774606571, COSV67308776, COSV67310749; called by muse, mutect2, varscan2
- GRM2 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1479216160, COSV56585073; called by muse, mutect2, varscan2
- GTF3C1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201606830, COSV62241425; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2AC17 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV58152728; called by muse, mutect2, varscan2
- H2BC14 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs760473010, COSV60797732; called by muse, mutect2, varscan2
- H2BC5 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV56801260; called by muse, mutect2, varscan2
- HAT1 | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51362781; called by muse, mutect2, varscan2
- HCK | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749578325, COSV52942862; called by muse, mutect2, varscan2
- HCN1 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301062; called by muse, mutect2
- HECTD1 | c.7657C>G p.L2553V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67944953, COSV67946409; called by muse, mutect2, varscan2
- HECTD2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV53221117; called by muse, mutect2, varscan2
- HECTD4 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566084907, COSV66386895; called by muse, mutect2, varscan2
- HECW1 | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761103115, COSV67823072; called by muse, mutect2, varscan2
- HELB | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV56073868; called by muse, mutect2, varscan2
- HELZ2 | c.7055T>C p.L2352P (on ENST00000467148 / NM_001037335.2; = p.L1783P on NM_033405.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV64442802; called by muse, mutect2, varscan2
- HENMT1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs770299698, COSV64230198; called by muse, mutect2, varscan2
- HERC5 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs778345432, COSV52038294, COSV52040064; called by muse, varscan2
- HID1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1019560789, COSV59351570; called by muse, mutect2, varscan2
- HIVEP2 | c.3454C>T p.H1152Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV50014273; called by muse, mutect2, varscan2
- HJURP | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs755034561, COSV64978645; called by muse, mutect2, varscan2
- HK2 | c.2587A>G p.T863A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV51875532; called by muse, mutect2, varscan2
- HLA-A | c.880del p.L294Sfs*3 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as COSV100954348; called by mutect2, varscan2
- HMCN1 | c.7311A>G p.S2437= | Splice Region (SNP) | VAF 33/99 reads (33%) | catalogued as COSV54902266; called by muse, mutect2, varscan2
- HNRNPF | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV61561050; called by muse, mutect2, varscan2
- HNRNPR | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs766971961, COSV56420054; called by muse, mutect2, varscan2
- HOXA2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV56065321; called by muse, mutect2
- HOXD1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1298677886, COSV58923576; called by muse, mutect2
- HPGD | c.307del p.T103Lfs*20 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV56661824; called by mutect2, pindel, varscan2
- HPSE | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs747014307, COSV60986921; called by muse, mutect2, varscan2
- HRNR | c.459A>C p.E153D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as COSV64258232; called by muse, mutect2, varscan2
- HSD17B13 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs373819787; called by mutect2, varscan2
- HSPA1L | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65149063; called by muse, mutect2, varscan2
- HSPG2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs751202082, COSV65971921; called by muse, mutect2, varscan2
- HTR6 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as rs1254870273, COSV53872813; called by muse, mutect2, varscan2
- HTRA2 | c.346del p.A116Qfs*93 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs779457274; called by mutect2, varscan2
- HUWE1 | c.11687G>A p.S3896N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV99470315; called by muse, mutect2, varscan2
- HYAL1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV56497665; called by muse, mutect2, varscan2
- ICAM5 | c.84G>A p.A28= | Splice Region (SNP) | VAF 4/17 reads (24%) | catalogued as rs759815089, COSV53425201; called by muse, mutect2, varscan2
- ID2 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99301035; called by muse, mutect2, varscan2
- IFRD2 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782492356, COSV57113751; called by muse, mutect2, varscan2
- IGHA1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs776369890; called by muse, mutect2, varscan2
- IGKV2-30 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs756684899; called by muse, mutect2, varscan2
- IGSF1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV63837639; called by muse, mutect2, varscan2
- IGSF3 | c.3313G>A p.G1105S (on ENST00000369486 / NM_001007237.3; = p.G1125S on NM_001542.4) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1032303341, COSV59591072; called by muse, mutect2, varscan2
- IHH | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773814022, COSV55393272; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- IL6ST | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61141354; called by muse, mutect2, varscan2
- IMMP1L | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV53444374; called by mutect2, varscan2
- IMPDH2 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489042065, COSV58707967; called by muse, mutect2
- IMPG2 | c.2726A>G p.N909S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51978694; called by muse, mutect2, varscan2
- INHBB | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV54677404; called by muse, mutect2, varscan2
- IPO13 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs183495352, COSV54837253, COSV54838372; called by muse, mutect2, varscan2
- IPO8 | c.2246G>A p.C749Y | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as COSV56241915; called by muse, mutect2, varscan2
- IQSEC3 | c.2925G>T p.K975N (on ENST00000538872 / NM_001170738.2; = p.K672N on NM_015232.1) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58285109; called by muse, mutect2, varscan2
- IRAK1BP1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV64048166; called by muse, mutect2, varscan2
- IRGC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs751629551, COSV54984288; called by muse, varscan2
- ISLR2 | c.536_537del p.Y179Sfs*65 | Frame Shift Del (DEL) | VAF 41/188 reads (22%) | catalogued as rs1310268253; called by mutect2, pindel, varscan2
- ITCH | c.2620C>T p.R874C (on ENST00000262650 / NM_001257137.3; = p.R833C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369656426, COSV52932194; called by muse, mutect2, varscan2
- ITGA3 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV50312537, COSV50327472, COSV50344193; called by muse, mutect2, varscan2
- ITGA5 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs949081104, COSV53217892; called by muse, mutect2, varscan2
- ITGA7 | c.3265G>A p.V1089I (on ENST00000555728; = p.V1045I on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as rs760064251, COSV57695607, COSV57701233; called by muse, mutect2, varscan2
- ITGA7 | c.1036G>A p.A346T (on ENST00000555728; = p.A302T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs750041574, COSV57692965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAL | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV63322308; called by muse, mutect2, varscan2
- ITGB1BP2 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV52137781; called by muse, mutect2, varscan2
- ITGB7 | c.1369C>A p.L457I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57238771; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs760028800; called by mutect2, varscan2
- IYD | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV57601290; called by muse, mutect2, varscan2
- JADE3 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV54466607; called by muse, mutect2, varscan2
- JADE3 | c.2468G>T p.R823M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54466616; called by muse, mutect2, varscan2
- JAG2 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs755251181, COSV59309224; called by muse, mutect2, varscan2
- JAK1 | c.605T>C p.M202T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61091314; called by muse, mutect2, varscan2
- JCAD | c.241del p.E81Sfs*69 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as COSV64759785; called by mutect2, pindel, varscan2
- JPH1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as COSV60611180; called by muse, mutect2, varscan2
- KAT2A | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555665176, COSV52425991; called by muse, mutect2, varscan2
- KAT2A | c.928del p.R310Afs*110 | Frame Shift Del (DEL) | VAF 31/155 reads (20%) | catalogued as COSV56792636; called by mutect2, pindel, varscan2
- KATNIP | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs773490373, COSV55181149; called by muse, mutect2, varscan2
- KCNA6 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54975363; called by muse, mutect2, varscan2
- KCNB2 | c.488_490del p.E163del | In Frame Del (DEL) | VAF 33/312 reads (11%) | catalogued as rs1320848071; called by mutect2, pindel, varscan2
- KCNG1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as rs755946302, COSV65367874; called by muse, mutect2, varscan2
- KCNH5 | c.2890dup p.Q964Pfs*9 | Frame Shift Ins (INS) | VAF 39/199 reads (20%) | catalogued as rs35940222; called by mutect2, varscan2
- KCNH5 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59761099; called by muse, mutect2, varscan2
- KCNJ3 | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54536397; called by muse, mutect2, varscan2
- KCNK1 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as COSV64035156; called by muse, mutect2, varscan2
- KCNMA1 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV54249910; called by muse, mutect2, varscan2
- KCNQ5 | c.1710-1G>A p.X570_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV59660871; called by muse, mutect2, varscan2
- KCNU1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765942865, COSV67755264; called by muse, mutect2, varscan2
- KCNU1 | c.1247A>T p.N416I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV67756219; called by muse, mutect2, varscan2
- KCTD11 | c.158C>T p.P53L (on ENST00000333751 / NM_001363642.1; = p.P14L on NM_001002914.2) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1315471375, COSV50136172; called by muse, mutect2, varscan2
- KCTD9 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55339890; called by muse, mutect2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM6B | c.1193C>G p.T398S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs529988217, COSV54681776; called by muse, mutect2, varscan2
- KDR | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172794960, COSV55765788; called by muse, mutect2, varscan2
- KIAA0100 | c.5980C>T p.R1994W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382126; called by muse, mutect2, varscan2
- KIAA1109 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1321902678, COSV52674377; called by muse, mutect2, varscan2
- KIDINS220 | c.3079A>G p.N1027D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV56753786; called by muse, mutect2, varscan2
- KIF18B | c.1586C>T p.T529M (on ENST00000593135 / NM_001265577.2; = p.T541M on NM_001264573.2) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751690765, COSV59273180; called by muse, mutect2, varscan2
- KIF19 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1383304149, COSV63429512; called by muse, mutect2, varscan2
- KIF26B | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63642017; called by muse, mutect2, varscan2
- KIF27 | c.2563C>A p.L855I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV52827948; called by muse, mutect2, varscan2
- KIF27 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52827967; called by muse, mutect2, varscan2
- KIF2A | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66945600, COSV66947545; called by muse, mutect2, varscan2
- KIFAP3 | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV63034096; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHL34 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746878234, COSV65279386; called by muse, mutect2, varscan2
- KLHL4 | c.1767C>A p.Y589* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV64142716; called by muse, mutect2, varscan2
- KLRG2 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV61800857; called by muse, mutect2, varscan2
- KMT2D | c.13403G>A p.R4468Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1214747607, COSV56442076; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KREMEN1 | c.919C>T p.R307C (on ENST00000407188; = p.R309C on NM_032045.5) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762595574, COSV100588538; called by muse, mutect2, varscan2
- KRTAP5-10 | c.250T>C p.C84R | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV64794800; called by muse, varscan2
- L1CAM | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs201882430, COSV62828174; called by mutect2, varscan2
- LAMA1 | c.8678C>T p.T2893I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV67537563; called by muse, mutect2, varscan2
- LAMA2 | c.809T>A p.V270D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70347750; called by muse, mutect2, varscan2
- LAMA2 | c.4282C>A p.L1428M | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1289838378, COSV70347754; called by muse, mutect2, varscan2
- LAMB2 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.632); catalogued as rs866448113, COSV100565577, COSV59733723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB4 | c.5042G>A p.S1681N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV52720088; called by muse, mutect2, varscan2
- LAMC1 | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs749477657, COSV51140763; called by muse, mutect2, varscan2
- LAMC2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs762028260, COSV51455676; called by muse, mutect2, varscan2
- LARGE1 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs368030516; called by muse, mutect2, varscan2
- LARP1B | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.415); catalogued as rs760176527, COSV52797861; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs746633076; called by mutect2, varscan2
- LCA5 | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | catalogued as rs765762174, CM1310825, COSV100878136; called by muse, mutect2, varscan2
- LCE3E | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as rs533619446, COSV64231813; called by muse, mutect2, varscan2
- LIAS | c.445C>T p.R149W (on ENST00000261434 / NM_001363700.2; = p.R252W on NM_006859.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775053206, COSV54695847; called by muse, mutect2, varscan2
- LILRA6 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.765); catalogued as rs751748933, COSV54432884, COSV54436661; called by muse, varscan2
- LIMK2 | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs138769386; called by mutect2, varscan2
- LIPG | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs748426191, COSV54296385; called by muse, mutect2, varscan2
- LMF2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs376834243; called by muse, mutect2, varscan2
- LMOD2 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs775214866, COSV71755596; called by muse, mutect2, varscan2
- LOXL2 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs754340605, COSV66691543; called by muse, mutect2, varscan2
- LPP | c.1324T>C p.F442L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57092386; called by muse, mutect2, varscan2
- LRAT | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010347467, COSV60477114; called by muse, mutect2, varscan2
- LRIG3 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs779709378, COSV57864019; called by muse, mutect2, varscan2
- LRP10 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs771796662, COSV62078300; called by muse, mutect2, varscan2
- LRP6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759106535, COSV53786736; called by muse, mutect2, varscan2
- LRRC32 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52633141; called by mutect2, varscan2
- LRRC49 | c.1400A>C p.N467T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs540252814, COSV53011058; called by muse, mutect2, varscan2
- LRRC52 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV54232271; called by muse, mutect2, varscan2
- LRRC8C | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV64998114; called by muse, mutect2, varscan2
- LRRN4CL | c.484A>C p.S162R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54015710; called by muse, mutect2, varscan2
- LSS | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); catalogued as rs1205750265, COSV62701014; called by muse, mutect2, varscan2
- LUC7L2 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV54926326; called by muse, mutect2, varscan2
- LUZP1 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs758820038, COSV56501247; called by muse, mutect2, varscan2
- LYPD2 | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1331103690, COSV63649481; called by muse, varscan2
- LYSMD3 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs1280667204, COSV60057236; called by muse, mutect2, varscan2
- LYST | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV67707235; called by muse, mutect2, varscan2
- LZTR1 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53147642; called by muse, mutect2
- LZTS2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs138910628; called by muse, mutect2, varscan2
- M6PR | c.453G>A p.A151= | Splice Region (SNP) | VAF 14/70 reads (20%) | catalogued as COSV50002991; called by muse, mutect2, varscan2
- MAGEB2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs200649828, COSV66780593; called by muse, mutect2, varscan2
- MAGEB6 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs749932015, COSV100983883, COSV66872315; called by muse, mutect2, varscan2
- MAGEB6B | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs745365301; called by muse, mutect2, varscan2
- MAN1C1 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56045210; called by muse, mutect2, varscan2
- MAP1A | c.5561del p.P1854Lfs*121 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs752048606, COSV100288337; called by mutect2, pindel, varscan2
- MAP1LC3C | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs112610111, COSV100606370; called by muse, mutect2, varscan2
- MAP3K4 | c.4173G>T p.L1391F | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV62333877; called by muse, mutect2, varscan2
- MAPK14 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs376583872; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs1383130845; called by mutect2, varscan2
- MARK1 | c.1138T>A p.S380T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV65067661; called by muse, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD2 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1202139329, COSV56501495; called by muse, mutect2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs746267361; called by mutect2, varscan2
- MBTPS1 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58570852; called by muse, mutect2, varscan2
- MC1R | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs376780075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDGA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV51796194; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs35107588; called by mutect2, pindel
- MED12L | c.5090A>G p.D1697G | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV56379891; called by muse, mutect2, varscan2
- MED24 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as rs532514222, COSV62418773; called by muse, mutect2, varscan2
- MEGF6 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775124579, COSV53890091; called by muse, mutect2, varscan2
- MEOX1 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59356216; called by muse, mutect2, varscan2
- MFHAS1 | c.2770C>G p.P924A | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1178988692, COSV52282448; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD2B | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV57854822; called by muse, mutect2, varscan2
- MFSD3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV56741091; called by muse, mutect2, varscan2
- MGAM | c.2749C>T p.H917Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.043); catalogued as COSV72074705; called by muse, mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MICOS13 | c.150dup p.A51Rfs*32 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs751944867; called by mutect2, varscan2
- MITF | c.1136G>A p.R379Q (on ENST00000448226 / NM_006722.3; = p.R279Q on NM_000248.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs775320252, COSV58831749; called by muse, mutect2, varscan2
- MMP17 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs374439053; called by muse, mutect2, varscan2
- MMS19 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs535028592, COSV59135187; called by muse, mutect2, varscan2
- MNDA | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.497); catalogued as rs1317651133, COSV63740853; called by muse, mutect2, varscan2
- MON2 | c.2939T>C p.F980S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1403525070, COSV54807644, COSV54809144; called by muse, mutect2, varscan2
- MRGPRX1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs375590109; called by muse, mutect2, varscan2
- MRTFA | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV62930909; called by muse, mutect2, varscan2
- MS4A6E | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as COSV55727015; called by muse, mutect2, varscan2
- MTF2 | c.1188dup p.G397Rfs*23 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFD2L | c.818T>C p.L273S (on ENST00000395759 / NM_001144978.2; = p.L215S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV57467473; called by muse, mutect2, varscan2
- MTHFS | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as rs777878165, COSV51913891; called by muse, mutect2, varscan2
- MUC16 | c.38132A>C p.K12711T | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV101200549, COSV67468280; called by muse, mutect2, varscan2
- MUC17 | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 176/586 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs768351156, COSV60289496; called by muse, mutect2, varscan2
- MUC17 | c.9919G>A p.D3307N | Missense Mutation (SNP) | VAF 147/581 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as rs1420733981, COSV60289504; called by muse, mutect2, varscan2
- MUC2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.78); catalogued as COSV61240017, COSV61244235; called by muse, mutect2, varscan2
- MVB12B | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1374009612, COSV63258566; called by muse, mutect2, varscan2
- MXRA8 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV58510640; called by muse, mutect2, varscan2
- MYBL2 | c.951G>A p.S317= | Splice Region (SNP) | VAF 28/110 reads (25%) | catalogued as rs774852019, COSV53827321, COSV99406635; called by muse, mutect2, varscan2
- MYBPC2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs752484451, COSV63095720; called by muse, mutect2, varscan2
- MYBPC2 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs775056269, COSV63094393; called by muse, mutect2, varscan2
- MYCBP2 | c.12620C>T p.S4207L (on ENST00000357337; = p.S4245L on NM_015057.5) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1340877066, COSV62020291; called by muse, mutect2, varscan2
- MYH11 | c.3143A>C p.K1048T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100257487; called by muse, mutect2, varscan2
- MYH6 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs587782959, COSV100676559, COSV62448174; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.4907G>A p.R1636H | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs770125496, COSV52680167; called by muse, mutect2, varscan2
- MYH9 | c.5807G>A p.R1936Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs781388651, COSV53386551; called by muse, mutect2
- MYO7B | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769391741, COSV67348010; called by muse, mutect2, varscan2
- MYO7B | c.5156C>T p.T1719M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776924200, COSV67348017; called by muse, mutect2, varscan2
- MYOF | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs181998538; called by muse, mutect2, varscan2
- MYORG | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1352720545, COSV52627244; called by muse, mutect2, varscan2
- NAAA | c.1001T>C p.F334S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54432247; called by muse, mutect2, varscan2
- NAALADL2 | c.2018T>C p.L673S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV71984721; called by muse, mutect2, varscan2
- NBEA | c.2929A>T p.K977* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV59786451, COSV59829993; called by muse, mutect2, varscan2
- NBEA | c.3769G>A p.A1257T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV59786461; called by muse, mutect2
- NBN | c.2025A>G p.I675M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV55373249; called by muse, mutect2, varscan2
- NCKAP1 | c.1864T>C p.C622R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100719863; called by muse, mutect2, varscan2
- NCKAP1L | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs202229208; called by muse, mutect2, varscan2
- NCKAP1L | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs779095429, COSV53207224; called by muse, mutect2, varscan2
- NCOR2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62298327; called by muse, mutect2, varscan2
- NDST2 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as rs199671198, COSV55214378; called by muse, mutect2, varscan2
- NDUFS2 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs754235300, COSV57155004; called by muse, mutect2, varscan2
- NECAB1 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV101340983, COSV70240145; called by muse, mutect2, varscan2
- NEDD4L | c.2464A>G p.K822E (on ENST00000400345 / NM_001144967.3; = p.K802E on NM_015277.6) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV56845240; called by muse, mutect2, varscan2
- NEK4 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs200701452; called by mutect2, varscan2
- NELL1 | c.35G>C p.C12S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.916); catalogued as COSV54267715; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 52/177 reads (29%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEUROD1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54549409; called by muse, mutect2
- NFASC | c.2252T>C p.M751T (on ENST00000339876 / NM_001378329.1; = p.M747T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767062575, COSV58366140; called by muse, mutect2, varscan2
- NFIB | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66620748; called by muse, mutect2, varscan2
- NFRKB | c.2501C>T p.P834L (on ENST00000446488 / NM_001143835.2; = p.P859L on NM_006165.3) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs756909237, COSV58758115; called by muse, mutect2, varscan2
- NGF | c.106C>A p.H36N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.133); catalogued as rs267597943, COSV65687468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIBAN2 | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64824458; called by muse, mutect2, varscan2
- NIN | c.3395C>T p.T1132M | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs139379777; called by muse, mutect2, varscan2
- NKAP | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65056242; called by muse, mutect2, varscan2
- NKX2-2 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65819628; called by muse, varscan2
- NKX2-2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV65819634; called by muse, varscan2
- NLGN3 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62443337; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NLRP3 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as rs1219334346, COSV60221224, COSV60224831; called by muse, mutect2, varscan2
- NLRP4 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV56714395; called by muse, mutect2, varscan2
- NMUR2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs963142407, COSV54919546; called by muse, mutect2, varscan2
- NOC2L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1424179005, COSV58531929; called by muse, mutect2, varscan2
- NOD2 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs142077546; ClinVar: uncertain significance; called by mutect2, varscan2
- NOD2 | c.2078G>A p.C693Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV56051046, COSV56051441; called by muse, mutect2, varscan2
- NONO | c.1208del p.P403Lfs*17 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs751687046; called by mutect2, pindel, varscan2
- NOP56 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs1329470584, COSV61389257; called by muse, mutect2, varscan2
- NOTCH1 | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53053122; called by muse, mutect2, varscan2
- NOTCH3 | c.3776G>A p.G1259D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54635322; called by mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 6/31 reads (19%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPBWR1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58696238; called by muse, mutect2, varscan2
- NPC1 | c.2177G>T p.R726M | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM146761, COSV52578980; called by muse, varscan2
- NPC2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1242060760, COSV53143460; called by muse, mutect2, varscan2
- NPHP3 | c.1720A>G p.I574V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as rs755013227, COSV58630295; called by muse, mutect2, varscan2
- NPR3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561075244, COSV54085059; called by muse, mutect2, varscan2
- NPY5R | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV58452100; called by muse, mutect2, varscan2
- NR2F1 | c.969A>C p.K323N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV59068443; called by muse, mutect2, varscan2
- NR5A2 | c.1363G>A p.V455M (on ENST00000367362 / NM_205860.3; = p.V409M on NM_003822.5) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV52650678; called by muse, mutect2, varscan2
- NRBP1 | c.591dup p.I198Hfs*9 | Frame Shift Ins (INS) | VAF 22/121 reads (18%) | catalogued as rs763892200; called by mutect2, varscan2
- NRDC | c.2390T>C p.V797A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV61404522; called by muse, mutect2, varscan2
- NRDC | c.1790T>A p.L597* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV61404532; called by muse, mutect2, varscan2
- NRF1 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs1217910568, COSV56212428; called by muse, mutect2, varscan2
- NRG3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV64563181; called by muse, mutect2, varscan2
- NRROS | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV60746026; called by muse, mutect2, varscan2
- NTM | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV66180457; called by muse, mutect2, varscan2
- NUCB2 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.802); catalogued as COSV60375319; called by muse, mutect2, varscan2
- NUDT13 | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV61968886; called by muse, mutect2, varscan2
- NUDT2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1312609869, COSV60678621; called by muse, mutect2, varscan2
- NUDT6 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52650093; called by muse, mutect2, varscan2
- NUP188 | c.1112A>T p.D371V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV65362377; called by muse, mutect2, varscan2
- NUP210 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs372920147; called by muse, mutect2, varscan2
- NUP50 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV61661067; called by muse, mutect2, varscan2
- OAZ3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375198253; called by muse, mutect2, varscan2
- OBSCN | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as rs757236748, COSV52776920; called by muse, mutect2, varscan2
- OBSCN | c.5332G>A p.V1778M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1351503081, COSV52776979; called by mutect2, varscan2
- OBSL1 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54719535; called by muse, mutect2, varscan2
- OFD1 | c.618A>C p.E206D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV60796073; called by muse, mutect2, varscan2
- OGFR | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV51699058; called by muse, mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, mutect2, varscan2
- OPRK1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs745533525, COSV55569565; called by muse, mutect2, varscan2
- OPRK1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.03); catalogued as rs369742092, COSV55569979; called by muse, mutect2, varscan2
- OR10J1 | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV71128891; called by muse, mutect2, varscan2
- OR10Z1 | c.174del p.M59Cfs*78 | Frame Shift Del (DEL) | VAF 72/313 reads (23%) | catalogued as COSV100779031; called by mutect2, pindel, varscan2
- OR13C4 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV52926758; called by muse, mutect2, varscan2
- OR1K1 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV52956568; called by muse, mutect2, varscan2
- OR1N1 | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV59195775; called by muse, mutect2, varscan2
- OR1S1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200142844, COSV58707165; called by muse, mutect2, varscan2
- OR2AK2 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63553179; called by muse, mutect2, varscan2
- OR2C1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs745873258, COSV59240296; called by muse, mutect2, varscan2
- OR5B12 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.56); catalogued as COSV56905119; called by muse, mutect2, varscan2
- OR6K6 | c.332C>A p.S111Y (on ENST00000368144; = p.S87Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV63744219, COSV63744589; called by muse, mutect2, varscan2
- OR8D1 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63442313; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs772802379; called by mutect2, varscan2
- OTUD4 | c.1108C>T p.P370S (on ENST00000447906 / NM_001366057.1; = p.P305S on NM_001102653.1) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.045); catalogued as COSV71381871; called by muse, mutect2, varscan2
- OTUD7A | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61039046; called by muse, mutect2, varscan2
- P3H2 | c.2059A>G p.I687V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV60021934; called by muse, mutect2, varscan2
- P4HA3 | c.875T>C p.I292T | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV59042000; called by muse, mutect2, varscan2
- PADI2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs768592470, COSV64945356, COSV64945916; called by muse, mutect2, varscan2
- PAFAH2 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV65339541; called by muse, mutect2, varscan2
- PAM | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209917; called by muse, mutect2, varscan2
- PAM | c.1564A>G p.K522E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57213479; called by muse, mutect2, varscan2
- PAPOLB | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.196); catalogued as COSV68200940; called by muse, mutect2, varscan2
- PAPPA | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs749158982, COSV60283885; called by muse, mutect2, varscan2
- PAPPA2 | c.1741del p.V581Lfs*4 | Frame Shift Del (DEL) | VAF 29/145 reads (20%) | catalogued as COSV62783931; called by mutect2, pindel, varscan2
- PAQR4 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202239569, COSV51891206; called by mutect2, varscan2
- PARP1 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV64690533; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBRM1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs554214396, COSV56277644, COSV56295607, COSV56303273; called by muse, mutect2, varscan2
- PC | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs764979642, COSV63080704; called by muse, mutect2, varscan2
- PCDH10 | c.360del p.S121Lfs*7 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | catalogued as rs759095467; called by mutect2, pindel, varscan2
- PCDH10 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52094513, COSV99994478; called by muse, mutect2, varscan2
- PCDH11X | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100007441; called by muse, mutect2, varscan2
- PCDH15 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as COSV57315299; called by muse, mutect2, varscan2
- PCDHA12 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.417); catalogued as COSV56475200; called by muse, mutect2, varscan2
- PCDHA6 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 73/374 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV67056572; called by muse, mutect2, varscan2
- PCDHA7 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554135772, COSV65343760, COSV65346769; called by muse, mutect2, varscan2
- PCDHB3 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 41/174 reads (24%) | catalogued as COSV50575896; called by muse, mutect2, varscan2
- PCDHB4 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.11); catalogued as rs1369557724, COSV52022820; called by muse, mutect2, varscan2
- PCDHB8 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV50770073; called by muse, mutect2, varscan2
- PCDHGA10 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs752898022, COSV53953279, COSV99543902; called by muse, mutect2, varscan2
- PCDHGA11 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV53953296; called by muse, mutect2, varscan2
- PCDHGB1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99529035; called by muse, mutect2, varscan2
- PCDHGB7 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.17); catalogued as rs772847766, COSV53922854; called by muse, mutect2, varscan2
- PCLO | c.10631A>G p.D3544G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61636897; called by muse, mutect2, varscan2
- PCNT | c.5890G>A p.A1964T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs772942335, COSV64028482; called by muse, mutect2, varscan2
- PCSK1N | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV99504732; called by muse, mutect2
- PCSK2 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV52733066; called by muse, mutect2, varscan2
- PCYT1A | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53057696; called by muse, mutect2, varscan2
- PCYT1A | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV53057706; called by muse, mutect2, varscan2
- PDCD11 | c.3353T>C p.L1118P | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63934071; called by muse, mutect2, varscan2
- PDE11A | c.2779G>A p.V927I | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs74326729, COSV53695431; called by muse, mutect2, varscan2
- PDE4D | c.905A>G p.E302G (on ENST00000340635 / NM_001104631.2; = p.E166G on NM_006203.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV58957217; called by muse, mutect2
- PDE4D | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs771006931, COSV72350366; called by muse, mutect2, varscan2
- PDGFC | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56849005; called by muse, mutect2, varscan2
- PDZD2 | c.4248del p.S1419Vfs*6 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs113511990, COSV56865110; called by mutect2, pindel, varscan2
- PER3 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV62705982; called by muse, mutect2, varscan2
- PFKFB1 | c.1010T>C p.M337T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | PolyPhen possibly damaging (0.573); catalogued as COSV66628424; called by muse, mutect2, varscan2
1,043 further variants in this file (622 protein-altering or splice-affecting, 395 silent, 26 other) are not listed here.
